Somatic mutation profile of tumor specimen MMRF_1090_1_BM_CD138pos (aliquot MMRF_1090_1_BM_CD138pos_T2_KAS5U_L02452) from MMRF case MMRF_1090, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.2 years (24,906 days).
Specimen MMRF_1090_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b235c5b-bd76-4f62-9b74-c8efd8e2409d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1090_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1090_1_PB_Whole_C3_KAS5U_L02463; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea4abaef-47fd-4dc4-92bc-79313404891d

The open-access MAF lists 157 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 47, Silent 21, Intron 13, 5'UTR 6, Splice Site 4, 3'Flank 4, 5'Flank 4, RNA 3, Nonsense Mutation 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>T p.D479V | Missense Mutation (SNP) | VAF 53/118 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- EVC | c.2449+1G>A p.X817_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as rs1553893423; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 76/164 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BEST1 | c.1334G>A p.W445* | Nonsense Mutation (SNP) | VAF 151/320 reads (47%) | catalogued as rs753051695; called by muse, mutect2, varscan2
- CEP290 | c.6917_6920del p.R2306Nfs*40 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs1177923180; called by mutect2, pindel, varscan2
- DNM1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs1275813509, COSV100360433, COSV57850426; called by muse, mutect2, varscan2
- GRIN2B | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV74207312; called by muse, mutect2, varscan2
- HS3ST3A1 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as rs1032353515; called by muse, mutect2, varscan2
- IGHJ3 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 22/28 reads (79%) | PolyPhen probably damaging (0.97); catalogued as rs376655414; called by muse, varscan2
- IGHJ5 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 33/63 reads (52%) | PolyPhen benign (0.086); catalogued as rs781822844; called by muse, varscan2
- IGLC3 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 32/42 reads (76%) | PolyPhen benign (0.112); catalogued as rs945901959; called by muse, varscan2
- MAPK1IP1L | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs550229007, COSV101133224; called by muse, mutect2, varscan2
- MYO15A | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs776819748, COSV52758962; called by muse, mutect2, varscan2
- NADK | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535936720; called by muse, mutect2, varscan2
- NUDT21 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55860199; called by muse, mutect2, varscan2
- OBSCN | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483740; called by muse, mutect2, varscan2
- OR5T2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV57589923, COSV57590240; called by muse, mutect2
- RFWD3 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63097025; called by muse, mutect2, varscan2
- SYT12 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774170606, COSV101210946; called by muse, mutect2, varscan2
- TTC17 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as rs766156231, COSV50007381; called by muse, mutect2
- TUSC3 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV65883907; called by muse, mutect2
- USP26 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs759318948, COSV100896752, COSV63709005; called by muse, mutect2, varscan2
- ZNF106 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1489105077; called by muse, mutect2, varscan2
- ARID2 | c.4285A>G p.S1429G | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- CADM2 | c.61+1G>T p.X21_splice | Splice Site (SNP) | VAF 118/247 reads (48%) | called by muse, mutect2, varscan2
- CCNQ | c.167A>C p.H56P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CELSR2 | c.4351C>T p.Q1451* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- CHRNA4 | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CHST14 | c.85_95dup p.L34Pfs*16 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CSMD1 | c.5021C>T p.A1674V (on ENST00000520002; = p.A1673V on NM_033225.6) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWC25 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHRS3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2
- DNAH14 | c.9775C>G p.L3259V (on ENST00000445597; = p.L4267V on NM_001367479.1) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDDM3B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- EFHC2 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- EPS8L3 | c.1391G>A p.R464K (on ENST00000361965 / NM_133181.4; = p.R434K on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- FBXO8 | c.276C>G p.C92W | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FMNL2 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- GMCL1 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HSPD1 | c.577_603del p.V193_V201del | In Frame Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel, varscan2
- IGHG1 | c.323_324del p.T108Mfs*8 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | called by pindel, varscan2
- KCNK1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MIS18BP1 | c.2782G>A p.G928R | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- MUSK | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NLRP11 | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 79/117 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- OFCC1 | n.2510G>T | Splice Region (SNP) | VAF 98/154 reads (64%) | called by muse, mutect2, varscan2
- PKP1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RRH | c.487T>G p.W163G | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHKBP1 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC36A4 | c.768G>T p.R256S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2
- SYNE2 | c.10212+2T>A p.X3404_splice | Splice Site (SNP) | VAF 40/94 reads (43%) | called by muse, varscan2
- TARM1 | c.301G>A p.G101R (on ENST00000616041 / NM_001330650.1; = p.G93R on NM_001135686.3) | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX10 | c.1957C>A p.L653I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLE4 | c.2137+2T>C p.X713_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- TMEM132B | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRPC7 | c.2440C>G p.Q814E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- USH1C | c.414T>A p.N138K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF205 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF37A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABCA8 | c.4572T>A p.A1524= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- CASP12 | c.330T>C p.Y110= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- CCNY | c.333C>T p.V111= | Silent (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- CHST13 | c.789C>T p.V263= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs374084728, COSV60042249; called by muse, mutect2, varscan2
- DOK1 | c.105C>T p.H35= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- EPHB2 | c.1266T>C p.P422= | Silent (SNP) | VAF 8/218 reads (4%) | catalogued as COSV65861940; called by muse, mutect2
- GPR18 | c.288T>C p.I96= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- HOXA11 | c.561G>A p.P187= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs542683559; called by muse, varscan2
- IFNE | c.378G>A p.L126= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as rs1309827228, COSV58640452; called by muse, mutect2, varscan2
- KLK13 | c.300G>T p.V100= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- MRPL44 | c.840G>A p.L280= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- NCAN | c.2745G>T p.V915= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- PDS5B | c.603A>T p.V201= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- PTPRCAP | c.594C>T p.G198= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- RNF168 | c.1530A>G p.P510= | Silent (SNP) | VAF 95/201 reads (47%) | called by muse, mutect2, varscan2
- SET | c.396A>G p.K132= (on ENST00000372692 / NM_001374326.1; = p.K119= on NM_003011.4) | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- SLC44A2 | c.853C>A p.R285= | Silent (SNP) | VAF 109/168 reads (65%) | called by muse, mutect2, varscan2
- TMEM151B | c.918G>A p.A306= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs879018632; called by muse, mutect2
- TMEM40 | c.672T>C p.F224= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- TRIM35 | c.162G>A p.S54= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV57766218; called by muse, mutect2, varscan2
- WDR81 | c.4476C>T p.F1492= (on ENST00000409644 / NM_001163809.2; = p.F441= on NM_152348.4) | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs1466776302; called by muse, mutect2, varscan2
- AADAT | c.-169G>A | 5'UTR (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1858-24G>C | Intron (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58639386; called by muse, mutect2, varscan2
- AC007342.3 | chr16:53371200 C>T | 5'Flank (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- AC100872.1 | chr8:122670306 del A | 5'Flank (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- ACP3 | c.*744A>G | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*835G>C | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- AL008638.2 | n.281C>A | RNA (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- AL109933.2 | n.18A>T | RNA (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- AMER2 | c.*7166C>A | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- ANKRD52 | c.*4726C>A | 3'UTR (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*2078G>C | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- ARMH4 | c.*3444G>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ASXL1 | c.*937A>G | 3'UTR (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- ATF7 | c.*103G>A | 3'UTR (SNP) | VAF 37/79 reads (47%) | catalogued as rs1284393708; called by muse, mutect2, varscan2
- BCL7A | chr12:122021513 G>A | 5'Flank (SNP) | VAF 31/65 reads (48%) | catalogued as COSV55848479; called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948345 T>A | 3'Flank (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- CEACAM1 | c.1247-2568A>G | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- CLSTN1 | c.*1254_*1260del | 3'UTR (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- COLCA2 | chr11:111296817 del C | 5'Flank (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- CYB561D1 | c.*1072C>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- DIP2A | c.*1511T>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs1044003443, COSV59478729; called by muse, mutect2, varscan2
- DLG1 | c.*951A>T | 3'UTR (SNP) | VAF 5/78 reads (6%) | catalogued as rs1023435182; called by muse, mutect2
- DPP4 | c.*621G>C | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- DSG3 | c.*2333A>C | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- EED | c.726+218A>C | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691030 A>C | 3'Flank (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- EPDR1 | c.*1245G>T | 3'UTR (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2, varscan2
- FAM53C | c.*956A>C | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2
- FAM53C | c.*958A>G | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2
- FLT1 | c.*351_*352delinsG | 3'UTR (DEL) | VAF 10/125 reads (8%) | called by mutect2*, pindel
- FOXD3 | c.-80C>T | 5'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- FOXE1 | c.*371G>A | 3'UTR (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- GPM6B | c.*308C>T | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- IGLC2 | c.*91T>C | 3'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, varscan2
- IQCJ | c.291+266C>T | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- KCNG1 | c.*9G>A | 3'UTR (SNP) | VAF 26/46 reads (57%) | catalogued as rs776244568; called by muse, mutect2, varscan2
- KIAA1549L | c.3988+300T>C | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- KLF13 | c.*611G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- KLF5 | c.*1595G>A | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- LAPTM5 | c.*802A>C | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- MAPK6 | c.*878del | 3'UTR (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- MSRB1 | c.*552G>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- MTR | c.*3908C>T | 3'UTR (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- MUC3A | c.9383-35C>T | Intron (SNP) | VAF 50/278 reads (18%) | catalogued as rs761489575; called by mutect2, varscan2
- MYO10 | c.279+2652G>T | Intron (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- NFIB | c.562+1005G>A | Intron (SNP) | VAF 126/434 reads (29%) | called by muse, mutect2, varscan2
- NPAS3 | chr14:33802373 A>G | 3'Flank (SNP) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- NPY2R | c.*146C>G | 3'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- OR4K15 | c.-42T>C | 5'UTR (SNP) | VAF 164/355 reads (46%) | called by muse, mutect2, varscan2
- OR9A2 | c.-2A>G | 5'UTR (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- PAX6 | c.11-592C>T | Intron (SNP) | VAF 49/117 reads (42%) | catalogued as rs537461367; called by muse, mutect2, varscan2
- PCDH15 | c.*1839del | 3'UTR (DEL) | VAF 35/88 reads (40%) | called by mutect2, pindel, varscan2
- PCNX2 | c.4077-595T>C | Intron (SNP) | VAF 31/69 reads (45%) | catalogued as rs1023537724; called by muse, mutect2, varscan2
- PGR | c.*3635G>C | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- QSOX1 | c.*4230A>G | 3'UTR (SNP) | VAF 5/62 reads (8%) | catalogued as rs1005637972; called by muse, mutect2
- ROBO1 | c.173-80056C>A | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2
- RSPH9 | c.*1145G>C | 3'UTR (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- SCN2B | c.-136T>C | 5'UTR (SNP) | VAF 69/152 reads (45%) | called by muse, mutect2, varscan2
- SEC14L3 | c.*59C>T | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- SEMA4B | c.*810C>T | 3'UTR (SNP) | VAF 13/429 reads (3%) | called by muse, mutect2
- SEZ6L2 | c.*132G>A | 3'UTR (SNP) | VAF 19/45 reads (42%) | catalogued as rs1447405816; called by muse, mutect2, varscan2
- SIRPA | c.*1348G>A | 3'UTR (SNP) | VAF 34/77 reads (44%) | catalogued as rs772615253; called by muse, mutect2, varscan2
- SLC39A8 | c.*755C>A | 3'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- SNTN | c.*892G>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- SNX17 | c.*480A>T | 3'UTR (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- SYT12 | c.*1006G>A | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- TMEM161B | c.914+71C>T | Intron (SNP) | VAF 95/143 reads (66%) | catalogued as rs1208425604, COSV56935038; called by muse, mutect2, varscan2
- TMEM175 | c.192+274C>G | Intron (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- TNKS | c.*4358G>C | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.*604A>T | 3'UTR (SNP) | VAF 50/83 reads (60%) | called by muse, mutect2, varscan2
- TP53I11 | c.*2429C>T | 3'UTR (SNP) | VAF 64/134 reads (48%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115411055 A>T | 3'Flank (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2
- VGLL3 | c.*133A>T | 3'UTR (SNP) | VAF 66/164 reads (40%) | called by muse, mutect2, varscan2
- WTAP | c.*523G>A | 3'UTR (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- ZNF286B | n.4700T>C | RNA (SNP) | VAF 101/276 reads (37%) | called by muse, mutect2, varscan2
- ZNF585A | c.-122C>G | 5'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs746331448; called by muse, mutect2, varscan2
- ZNF92 | c.*622A>C | 3'UTR (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
